Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6188, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6188-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Brain tumor: anaplastic astrocytoma, grade III of IV (WHO scale), see microscopic description, see comment
2. Brain tumor: anaplastic astrocytoma, grade III of IV (WHO scale), see microscopic description, see comment

Comment:

The proliferation index is within the expected range for an anaplastic astrocytoma, grade III of IV (WHO scale). Selected slides were reviewed by [REDACTED] who concurs with the presence of malignancy in this material.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately pleomorphic and densely cellular proliferation of astrocytes. There are few scattered mitoses. There is no endothelial proliferation or necrosis. Immunohistochemistry for the proliferation antigen Ki67 was performed as follows: Four 250 x 250 micron fields were counted and the percentage of labeled nuclei determined. Over 1000 cells were counted. The proliferation index ranged from 4.3% to 12.1% with an overall average of 9.5%.

Section Diagnosis:

[REDACTED]

[page 2 of 3]
1. Brain tumor: Infiltrative glioma, no definitive high-grade features identified on representative frozen section

Clinical History and Diagnosis:

Image guided right side craniotomy resection of mass

Source of Specimen:

1: Brain tumor

2: Brain tumor

[REDACTED], in a specimen container labeled with the patient's name and "#1 brain tumor", is a 1.4 x 0.8 x 0.3 cm aggregate of soft tan-pink tissue. Approximately 60% of the specimen is submitted for frozen section analysis. Touch preparations are made. The remainder of the specimen is entirely submitted in 2 cassettes as follows:

A. frozen section control

B. remainder of specimen

2. Brain tumor: Received in formalin, in a specimen container labeled with the patient's name and "#2 brain tumor", is a 0.5 x 0.5 x 0.1 cm fragment of soft tan-pink tissue. The entire specimen is submitted in one cassette.

tology Laboratory

Immunohistochemistry Notes

1. Quantification of [REDACTED] istry assay for ER and PR studies
[REDACTED] od of [REDACTED] Applied Immunohistochemistry,
[REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded.

Interpretation foll [REDACTED] rer' s rec

y [REDACTED], et.al. [REDACTED] Vol

[page 3 of 3]
EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded.
Interpretation follows [REDACTED] turer' s
[REDACTED] et.al. [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their
determined by the Clinical Laboratory of [REDACTED]
Hospital.

They have not been cleared by the US Food and Drug Administration.
The FDA has determined that such clearance or approval is not
necessary.

Source: NCI Genomic Data Commons file dce7f459-4bde-4e30-aace-92ef6aa41360 (TCGA-CS-6188.E85D2DDF-98E1-4A02-BDE1-47603463F7FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).